Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A91D, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A91D-01A (Primary Tumor).

Collect date:

ICD O-3

Adenocarcinoma, intestinal
Type 8144/3

Site: Body & Stomach C16.2
JES 3/18/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

"1-Stomach + D2 lymphadenectomy + right extended colectomy:

- Invasive ulcerated moderately differentiated adenocarcinoma, Lauren's intestinal type.
- Size of neoplasia: 5.0x4.5x4.0 cm.
- Invasion level: serosa and adjacent fat tissue, with involvement of omentum and colon to submucosa, with ulceration of mucosa.
- Blood vessel invasion: present.
- Lymphatic invasion: present.
- Perineural invasion: present.
- Adjacent mucosa: inactive discrete chronic gastritis.
- Surgical margins (stomach and colon): uninvolved by neoplasia.
- Five out of 33 examined perigastric lymph nodes involved by neoplasia (5/33), with capsular invasion, without conglomerate formation.

2-Perisplenic omentum:

- Lymph node uninvolved by neoplasia (0/1).

3-Transverse mesocolon lymph node:

- Uninvolved by neoplasia (0/3).

4-Esophageal margin:

- Uninvolved by neoplasia.

5- Lymph nodes following standardization:

- Five lymph nodes uninvolved by neoplasia (0/5), distributed as follows:
- Chain 8 – anterior hepatic artery (8a): 0/1.
- Chain 11 – proximal splenic artery (11p): 0/3.
- Chain 12 – hepatoduodenal ligament (12a): 0/1."

Gravito	11/5/13	Yes	No
Diagnosis of Neoplasia			
ICD/A Discrepancy			
Prior History			
Pathologic History			
Case is (re)classified			
Case is (re)classified			
Review of Initial			
Review of Initial			

Source: NCI Genomic Data Commons file 9ce3355f-78a8-44ba-8e96-1c6b78f193e5 (TCGA-VQ-A91D.F5B634C5-2C5B-40D6-863A-036089FB5AD3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).